Somatic mutation profile of tumor specimen TARGET-40-NAAGJY-01A (aliquot TARGET-40-NAAGJY-01A-01D) from TARGET case TARGET-40-NAAGJY, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 10.7 years (3,922 days).
Specimen TARGET-40-NAAGJY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6aceae3f-2a5b-4298-956d-e74f38729d37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJY-10A (Blood Derived Normal), aliquot TARGET-40-NAAGJY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b388949f-e7e9-405c-8383-934691f0a58f

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Intron 3, Frame Shift Del 1, IGR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAT1 | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs112658000; ClinVar: uncertain significance; called by muse, mutect2
- KCNJ1 | c.515C>G p.S172C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV60661801; called by muse, mutect2, varscan2
- MPL | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 83/304 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as COSV100991877; called by muse, mutect2, varscan2
- MYOCD | c.2468T>C p.V823A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV58506709; called by muse, mutect2
- PXDN | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs1305521141; called by muse, varscan2
- UGT1A6 | c.1484T>G p.L495W | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM002652; called by muse, mutect2, varscan2
- USP9Y | c.7607G>A p.R2536Q | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.006); catalogued as rs777843304; called by muse, mutect2, varscan2
- ATAD2B | c.3059C>T p.A1020V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.072); called by muse, varscan2
- GDF3 | c.742A>G p.K248E | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- IFT122 | c.2449A>G p.K817E (on ENST00000348417 / NM_052989.3; = p.K758E on NM_018262.4) | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, varscan2
- MAMDC2 | c.1982C>A p.A661E | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.438); called by muse, varscan2
- SRD5A2 | c.738del p.A248Pfs*31 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | called by mutect2, pindel, varscan2
- TLE2 | c.694A>T p.K232* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- VPS26B | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- ZNF638 | c.5149G>A p.D1717N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CFTR | c.78A>G p.K26= | Silent (SNP) | VAF 22/45 reads (49%) | called by muse, varscan2
- COP1 | c.1956A>G p.G652= | Silent (SNP) | VAF 11/13 reads (85%) | called by muse, mutect2, varscan2
- TECTA | c.1512C>T p.V504= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs376261886; called by muse, mutect2, varscan2
- TICRR | c.2296C>T p.L766= | Silent (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- ADAM10 | c.207-9233C>T | Intron (SNP) | VAF 9/13 reads (69%) | catalogued as rs1178829802; called by muse, mutect2, varscan2
- COL18A1 | c.3928+847C>A | Intron (SNP) | VAF 37/108 reads (34%) | called by muse, mutect2, varscan2
- FAM13A | c.1008-17979G>T | Intron (SNP) | VAF 3/13 reads (23%) | called by muse, varscan2
- Unknown | chr7:55699052 del C | IGR (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
